Gene-level copy-number profile of tumor specimen TCGA-A2-A0EN-01A from TCGA case TCGA-A2-A0EN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.6 years (25,771 days).
Specimen TCGA-A2-A0EN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.38decb88-ca75-4a0c-bdd2-917ccdd60851.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0EN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 361 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a4612e3f-8340-4882-903b-91c17cd76004

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 643; copy number 1: 8,889; copy number 2: 43,697; copy number 3: 2,610; copy number 4: 4,206; copy number 5: 186; copy number 6: 23; copy number 7: 5; copy number 10: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0EN-01A-13D-A087-01): tumor purity 0.42, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 122 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:65,415,816–68,202,987, 41 genes (within-gene range 0–1): RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1, AL513493.1, RN7SL854P, PDE4B, PDE4B-AS1, RNU4-88P, SGIP1, MIR3117, AL139147.1, TCTEX1D1, INSL5, DNAI4, AL592161.1, MIER1, SLC35D1, C1orf141, AL133320.1, AL133320.2, IL23R, RNU6-586P, RNU4ATAC4P, DNAJB6P4, IL12RB2, SERBP1, RNU6-387P, LINC01702, RNU6-1031P, AL590559.1, RN7SL392P, HNRNPCP9, GADD45A, GNG12, RNU7-80P, GNG12-AS1, AL157407.1, DIRAS3, ARL5AP3.
- chr4:89,836,408–89,841,978, 1 gene: SNCA-AS1.
- chr5:178,840,097–178,841,134, 1 gene: AC126915.1.
- chr13:70,564,267–70,564,437, 1 gene: AL445264.1.
- chr14:21,990,496–22,505,167, 71 genes (broad region; genes not listed).
- chr17:16,525,832–16,667,118, 7 genes: AC127540.2, ZNF287, AC127540.1, SRSF6P2, ZNF624, AC098850.2, NEK4P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 215 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–46,028,892, 1 gene, copy number 6: AC118650.1.
- chr13:18,467,172–18,871,967, 17 genes, copy number 6 (within-gene range 2–6): ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3.
- chr14:105,664,633–106,875,071, 190 genes, copy number 5–6 (broad region; genes not listed).
- chr17:36,601,583–36,608,964, 1 gene, copy number 10 (within-gene range 2–10): MRM1.
- chr17:46,029,916–46,225,389, 1 gene, copy number 5 (within-gene range 2–7): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 7: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 8,889. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
